Somatic mutation profile of tumor specimen MP2PRT-PAWCGJ-TMP1-A (aliquot MP2PRT-PAWCGJ-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAWCGJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,424 days).
Specimen MP2PRT-PAWCGJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd15e151-2d22-4ddd-a4d4-8009815283e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCGJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCGJ-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa0e04ca-2370-4a58-accd-8d85fcfb9855

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, 3'Flank 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 52/302 reads (17%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- DOT1L | c.973T>A p.Y325N | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67112195; called by muse, mutect2, varscan2
- DYNLT3 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 39/615 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs367889176; called by muse, mutect2
- GK | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs778896051, COSV66735498; called by muse, mutect2, varscan2
- KIF26A | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 68/760 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757921413, COSV59470792; called by muse, mutect2
- MAGEB5 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 159/380 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs752349383; called by muse, mutect2, varscan2
- MYH10 | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767545696, COSV52613252; called by muse, mutect2
- OTOG | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767477355; called by muse, mutect2, varscan2
- SLC22A1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 118/522 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175649502; called by muse, varscan2
- SLC25A31 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 114/417 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV55420403; called by muse, mutect2, varscan2
- TAF2 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV65419501; called by muse, mutect2, varscan2
- TSPAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753573127, COSV65690375; called by muse, mutect2, varscan2
- ADAM29 | c.700T>A p.S234T | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DEFB113 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 127/439 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH18 | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM6 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SLC35G1 | c.1085A>G p.Q362R (on ENST00000427197 / NM_001134658.3; = p.Q361R on NM_153226.4) | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TRPA1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- BEND7 | c.1206G>A p.Q402= | Silent (SNP) | VAF 108/510 reads (21%) | called by muse, varscan2
- LRRC37B | c.732C>T p.N244= | Silent (SNP) | VAF 52/370 reads (14%) | catalogued as rs200519924; called by muse, mutect2, varscan2
- MXRA5 | c.5379G>A p.P1793= | Silent (SNP) | VAF 152/473 reads (32%) | catalogued as rs748301955, COSV99477924; called by muse, mutect2, varscan2
- SIN3A | c.3696G>A p.K1232= | Silent (SNP) | VAF 54/563 reads (10%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 ins A | 3'Flank (INS) | VAF 23/160 reads (14%) | called by pindel, varscan2
- IGLV8-61 | chr22:22099212 ins GGGT | 3'Flank (INS) | VAF 64/168 reads (38%) | called by mutect2, pindel, varscan2
- SLC25A48 | c.813+529C>T | Intron (SNP) | VAF 117/442 reads (26%) | called by muse, mutect2, varscan2
